Somatic mutation profile of tumor specimen TCGA-97-7552-01A (aliquot TCGA-97-7552-01A-11D-2036-08) from TCGA case TCGA-97-7552, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.0 years (25,578 days).
Specimen TCGA-97-7552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bd40519-bbf9-4820-8629-b7d5b0a2eb8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-7552-10A (Blood Derived Normal), aliquot TCGA-97-7552-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e89e47e9-d2f5-4bb9-b067-e68476b3bd28

The open-access MAF lists 34 somatic variants for this specimen: 20 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 13, Frame Shift Del 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as COSV53571243; called by muse, mutect2, varscan2
- CFAP47 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs749241599, COSV57971117; called by muse, mutect2
- EPB41L3 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59443313; called by muse, mutect2
- GDF9 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV51525730; called by muse, mutect2, varscan2
- KRTAP24-1 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as COSV61088961; called by muse, mutect2
- LCOR | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV63629881; called by muse, mutect2
- MTA2 | c.1382T>C p.L461P | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53468588; called by muse, mutect2, varscan2
- NAV3 | c.3592G>T p.D1198Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57059835; called by muse, mutect2
- NKX2-1 | c.229del p.Q77Sfs*18 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as CM1314552; called by mutect2, pindel, varscan2
- PLA2G4C | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV62783779, COSV62787719; called by muse, mutect2, varscan2
- PYGM | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs750700202, CM063084, COSV51214790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB11FIP4 | c.815T>A p.V272D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV57926115; called by muse, mutect2, varscan2
- RHOT2 | c.1040G>C p.R347P | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.29); catalogued as COSV53466136; called by muse, mutect2
- ROCK1 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV67694225; called by muse, mutect2
- SAMHD1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1311797673, COSV53428109; called by muse, mutect2
- SERPINA5 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs750522516, COSV61573535; called by muse, mutect2, varscan2
- SMG5 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV55293025; called by muse, mutect2
- UNC5B | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58974066; called by muse, mutect2
- SEC22A | c.767_768del p.S256Ffs*16 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | called by mutect2, varscan2
- ZNF746 | c.792del p.C265Afs*6 | Frame Shift Del (DEL) | VAF 16/124 reads (13%) | called by mutect2, varscan2
- AP2A1 | c.2403C>G p.L801= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV58240717; called by muse, mutect2, varscan2
- CGGBP1 | c.54T>C p.A18= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV58851307; called by muse, mutect2
- DIRAS1 | c.432C>T p.C144= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs1391849282, COSV60214917; called by muse, mutect2, varscan2
- MED12 | c.1602G>A p.A534= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1057523461, COSV61330145; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.39216G>A p.K13072= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV66689607; called by muse, mutect2
- NLRP13 | c.306A>G p.R102= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV61619723; called by muse, mutect2, varscan2
- OR4C13 | c.577C>T p.L193= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV101634199, COSV73648605; called by muse, mutect2, varscan2
- RYR1 | c.5481C>T p.R1827= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as COSV62087881, COSV62106925; called by muse, mutect2, varscan2
- ST6GAL2 | c.1482C>A p.R494= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV62415779; called by muse, mutect2
- SUPT6H | c.885T>G p.P295= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV58924296; called by muse, mutect2
- TMEM67 | c.171C>A p.I57= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as COSV60035381; called by muse, mutect2, varscan2
- TTN | c.99138T>A p.L33046= (on ENST00000591111; = p.L25622= on NM_003319.4) | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV59870564; called by muse, mutect2
- ZNF200 | c.745A>C p.R249= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV67723548; called by muse, mutect2
- MAP3K20 | c.987+4138A>C | Intron (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100169440; called by muse, mutect2, varscan2
